Surgical pathology report (de-identified scan), TCGA case TCGA-DI-A2QT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MD Anderson, specimen TCGA-DI-A2QT-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

DIAGNOSIS

ICB-0-3

carcinoma, serous (8441/3)
and clear cell (8310/3)
code to highest - 8441/3

Site: endometrium c54.1

lw
9/3/11

- (A) FALCIFORM LIGAMENT, BIOPSY:
Fibroadipose tissue, negative for carcinoma.
- (B) OMENTUM, RESECTION:
Fibroadipose tissue, negative for carcinoma.
- (C) LEFT TUBE AND OVARY, TUBO-OOPHORECTOMY:
RIGHT OVARY: HIGH-GRADE PAPILLARY SEROUS CARCINOMA WITH FOCAL CLEAR CELL CARCINOMA INVOLVING THE OVARY, 6.0 CM IN GREATEST DIMENSION.
RIGHT FALLOPIAN TUBE: INVOLVED BY HIGH GRADE CARCINOMA
- (D) UTERUS, RIGHT FALLOPIAN TUBE, RIGHT OVARY, HYSTERECTOMY AND RIGHT TUBO-OOPHORECTOMY:
UTERUS: PAPILLARY SEROUS CARCINOMA AND CLEAR CELL CARCINOMA, CIRCUMFERENTIALLY INVOLVING THE ENDOMETRIUM, MYOMETRIUM, AND LOWER UTERINE SEGMENT.
TUMOR EXTENSIVELY INVADING INTO THE MYOMETRIUM, 18/19 MM AT THE LEVEL OF ANTERIOR UTERINE WALL AND 25/26 MM AT THE LEVEL OF POSTERIOR UTERINE WALL.
EXTENSIVE LYMPHOVASCULAR INVASION.
MULTIPLE LEIOMYOMAS INVOLVED BY PAPILLARY SEROUS CARCINOMA.
CERVIX: MIXED PAPILLARY SEROUS CARCINOMA AND FOCAL CLEAR CELL CARCINOMA INVOLVING ENDOCERVIX AND VAGINAL CUFF.
TUMOR EXTENSIVELY INVOLVES PERICERVICAL SOFT TISSUE WITH FOCAL EXTENSION INTO PARAMETRIAL RESECTION MARGIN.
RIGHT OVARY: HIGH GRADE PAPILLARY SEROUS CARCINOMA.
RIGHT FALLOPIAN TUBE: HIGH GRADE SEROUS CARCINOMA (SEE COMMENT).
- (E) LEFT PELVIC LYMPH NODE, LYMPHADENECTOMY:
THREE OUT OF FIVE LYMPH NODES INVOLVED BY METASTATIC CARCINOMA (3/5)
- (F) RIGHT PELVIC LYMPH NODES, LYMPHADENECTOMY:
FOUR OUT OF TEN LYMPH NODES INVOLVED BY METASTATIC CARCINOMA (4/10).
- (G) PARAAORTIC LYMPH NODES, LYMPHADENECTOMY:
TEN LYMPH NODES INVOLVED BY METASTATIC CARCINOMA (10/10).
- (H) RIGHT GONADAL VESSEL, EXCISION:
FOCAL HIGH-GRADE SEROUS PAPILLARY CARCINOMA ADJACENT TO VESSEL WALL, 0.5 CM IN GREATEST DIMENSION.
- (I) LEFT COMMON LYMPH NODE, LYMPHADENECTOMY:
TWO OUT OF THREE LYMPH NODES INVOLVED BY METASTATIC CARCINOMA (2/3).

COMMENT

The tumors in the uterus/cervix and bilateral ovaries show similar morphology. Tumor infiltrates through the entire full-thickness of the myometrium as well as the ovaries, therefore it is difficult to establish the primary site, although an endometrial primary is favored.

CROSS DESCRIPTION

Reviewed Initials	EWG	

[page 2 of 3]
(A) CALCIFORM LIGAMENT - A fragment of fatty soft tissue measuring 3.0 x 3.0 x 1.0 cm. No focal lesions are identified within the specimen, except for a small area of what appears to be fibrosis. That focus plus representative sections are submitted.
SECTION CODE: A1, fibrotic tissue; A2-A5, additional representative sections.

(B) OMENTUM - A fragment of fatty soft tissue measuring 30.0 x 16.0 x 1.0 cm. No focal lesions are identified within the specimen. Representative sections are submitted.

SECTION CODE: B1-B20, representative sections.

(C) LEFT TUBE, LEFT OVARY - An unilateral salpingo-oophorectomy.

The ovary measures 6.0 x 4.0 x 3.0 cm. Cut surface shows complete replacement of the ovary with a multilobulated, glistening yellow tumor with focal white areas.

The fallopian tube measures 7.0 cm in length x 1.0 cm in diameter. The fallopian tube has a small 0.2 cm white nodule. Otherwise, the fallopian tube is unremarkable. Sections are submitted as follows.

SECTION CODE: C1-C3, representative sections of ovary for frozen section; C4, representative section of fallopian tube with nodule for frozen section; C5-C10, representative sections of ovarian tumor; C11, representative sections of unremarkable fallopian tube.

*FS/DX: HIGH-GRADE CARCINOMA WITH CL CELL FEATURES INVOLVING OVARY, FAVOR METASTASIS FROM ENDOMETRIUM.

(D) UTERUS, RIGHT FALLOPIAN TUBE, RIGHT OVARY - A 9.8 x 7.0 cm uterus with attached 4.0 x 4.0 x 3.0 cervix and right ovary and fallopian tube which measure 4.0 x 3.0 x 1.5 cm ovary, 5.0 cm in length and 0.5 cm in diameter fallopian tube. The uterus is markedly distorted by multiple nodules. The serosal surface is tan-red, glistening and unremarkable. There is a fungating mass protruding from the cervical os which is friable in consistency. After being bisected, there is a 3.5 x 3.0 x 0.8 cm lesion located in the cervical canal protruding through the cervical os. The third portion of the cervical canal has no grossly identifiable lesion. The endometrial cavity is distorted by a large nodule which upon sectioning has tan-gray, rubbery and has whorled appearance. The endometrium measures 5.0 x 4.0 cm and is filled by a soft friable hemorrhagic tumor throughout the whole endometrial cavity. The right ovary is distorted by multiple nodules. Fallopian tube is grossly unremarkable. There is a small portion of vaginal cuff attached to the cervix and is grossly unremarkable.

INK CODE: Cervical margin, vaginal cuff margins are inked black.

SECTION CODE: D1, D2, anterior vaginal cuff en face; D3, posterior vaginal cuff, en face; D4-D6, lower portion of the cervix submitted perpendicularly from anterior to left quadrant; D7-D10, cervix anterior to right quadrant; D10-D12, cervix, posterior to right quadrant; D13-D15, cervix posterior to left quadrant; D16, representative section of the tumor located in the lower portion of the cervix; C17-C18, grossly uninvolved anterior portion of the cervix; D19, grossly unremarkable portion of the posterior upper cervix; D20-D22, representative sections of the tumor in the anterior endometrium with relation to serosal surface; D23-D25, tumor in the posterior endometrium; D26, D27, remaining parametrium submitted en face; D28, right fallopian tube and ovary; D29-D34, representative sections of fibroids.

(E) LEFT PELVIC LYMPH NODE - Multiple lymph nodes ranging in diameter from 2.0 cm to 2.9 cm. A 2.1 cm lymph node has a possible focus of carcinoma measuring 1.6 cm. Sections are submitted as follows.

SECTION CODE: E1, E2, one lymph node trisected with possible gross tumor; E3, E4, one lymph node bisected; E5, one lymph node bisected; E6-E8, one lymph node serially sectioned; E9, one lymph node serially sectioned.

(F) RIGHT PELVIC LYMPH NODES - Multiple lymph nodes measuring in diameter from 0.2 to 6.0 x 0.5 cm. Sections are submitted as follows.

SECTION CODE: F1, F2, one lymph node serially sectioned; F3, four possible lymph nodes; F4, two possible lymph nodes; F5, one lymph node bisected; F6, two possible lymph nodes; F7-F11, one lymph node serially sectioned.

(G) PARAAORTIC LYMPH NODES - An elongated piece of tan-red, rubbery tissue intermixed with adipose-like tissue which measures 12.0 x 2.5 x 1.8 cm with a separate tan-yellow adipose-like tissue with grossly identifiable lymph nodes which measures 2.5 x 1.9 x 0.8 cm. The specimen is submitted in representative sections as follows.

SECTION CODE: G1, one lymph node bisected; G2, one lymph node bisected; G3, one lymph node bisected; G4, one lymph node bisected; G5, one lymph node bisected; G6, one lymph node bisected; G7, one lymph node bisected; G8, G9, one large lymph node serially sectioned; G10-G12, multiple matted lymph nodes.

(H) RIGHT GONADAL VESSEL - An unoriented 5.0 cm segment of vessel with attached fatty tissue measuring 2.0 x 5.0 x 2.0 cm. There is a small focus of firmness adjacent to the vessel and compressing the wall, measuring approximately 0.3 x 0.3 x 2.0 cm. The entire specimen is submitted.

SECTION CODE: H1, proximal and distal vessel; H2-H8, serial sections.

(I) LEFT COMMON LYMPH NODE - An irregular piece of tan-red adipose tissue like tissue with grossly recognizable lymph nodes. Specimen measures 2.8 x 2.3 x 0.9 cm. The specimen is submitted in toto in two cassettes.

[page 3 of 3]
Specimen Date/Time: (

SECTION CODE: I1, one lymph node bisected; I2, three lymph nodes with adjacent adipose like tissue. I

CLINICAL HISTORY

Endometrial cancer

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by I specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 85baa525-7d37-47e5-95cc-936884389263 (TCGA-DI-A2QT.416DF035-67B0-4461-9523-EB4A4A1FBA5B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).